Somatic mutation profile of tumor specimen TCGA-A6-A5ZU-01A (aliquot TCGA-A6-A5ZU-01A-11D-A28G-10) from TCGA case TCGA-A6-A5ZU, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 59.0 years (21,554 days).
Specimen TCGA-A6-A5ZU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 609f6802-6790-409a-bf35-7f1572e5daee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-A5ZU-10A (Blood Derived Normal), aliquot TCGA-A6-A5ZU-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c7d9a26-c56a-451b-b72c-2c1e5ed9c6a4

The open-access MAF lists 109 somatic variants for this specimen: 71 protein-altering or splice-affecting, 29 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 29, Nonsense Mutation 4, 3'UTR 4, Frame Shift Del 3, Splice Region 2, RNA 2, In Frame Del 1, Splice Site 1, 3'Flank 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4127_4128del p.Y1376Cfs*9 | Frame Shift Del (DEL) | VAF 47/88 reads (53%) | catalogued as rs1554085533; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 102/140 reads (73%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ADCY2 | c.2385A>G p.R795= | Splice Region (SNP) | VAF 16/72 reads (22%) | catalogued as rs142191090; called by muse, mutect2, varscan2
- ADGRL3 | c.3728G>A p.R1243H (on ENST00000506720 / NM_001322402.2; = p.R1175H on NM_015236.6) | Missense Mutation (SNP) | VAF 168/252 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746720564; called by muse, varscan2
- COL1A2 | c.2288G>T p.G763V | Missense Mutation (SNP) | VAF 79/148 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs72658179, CM973119, HM090038; called by muse, mutect2, varscan2
- DLX5 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.229); catalogued as rs1019627015; called by muse, mutect2, varscan2
- DNAH2 | c.11140G>A p.V3714M | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs1402571866; called by muse, mutect2, varscan2
- DOP1B | c.3066C>T p.A1022= | Splice Region (SNP) | VAF 12/29 reads (41%) | catalogued as rs546032271; called by muse, mutect2, varscan2
- EDIL3 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56908131; called by muse, mutect2, varscan2
- EXPH5 | c.3328G>A p.V1110I | Missense Mutation (SNP) | VAF 53/69 reads (77%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs568354887, COSV56200353, COSV56204514; called by muse, mutect2, varscan2
- FLNA | c.6416G>A p.R2139Q (on ENST00000369850 / NM_001110556.2; = p.R2131Q on NM_001456.3) | Missense Mutation (SNP) | VAF 132/172 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV100774603; called by muse, mutect2, varscan2
- GALNT17 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 138/231 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs768467394, COSV61156096, COSV61169634; called by muse, mutect2, varscan2
- GPR52 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 100/141 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772421714, COSV52321174; called by muse, mutect2, varscan2
- GRIK2 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 81/106 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs755777802, COSV59784426; called by muse, mutect2, varscan2
- ITGAX | c.3091C>T p.R1031C | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as rs377108919; called by muse, mutect2, varscan2
- KRT5 | c.1234A>T p.N412Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV99358357; called by mutect2, varscan2
- MCM9 | c.3289C>T p.R1097C | Missense Mutation (SNP) | VAF 101/144 reads (70%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as rs1298913510, COSV60326625; called by muse, mutect2, varscan2
- MDGA2 | c.1360C>T p.R454W (on ENST00000399232 / NM_001113498.2; = p.R156W on NM_182830.4) | Missense Mutation (SNP) | VAF 112/156 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs775365673, COSV62078893; called by muse, mutect2, varscan2
- MEAK7 | c.79T>A p.L27M | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs1283469351; called by muse, mutect2, varscan2
- MYF6 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV57351382; called by muse, mutect2, varscan2
- NEUROD4 | c.973C>T p.L325F | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV54471972; called by muse, mutect2
- NLRC3 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 91/126 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761616730; called by muse, mutect2, varscan2
- OR51I1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 108/161 reads (67%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.768); catalogued as rs138548705, COSV66507243; called by muse, mutect2, varscan2
- PARVB | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs534947819, COSV100115007; called by muse, mutect2, varscan2
- PBRM1 | c.2506C>T p.R836W | Missense Mutation (SNP) | VAF 54/75 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438592568, COSV56266126; called by muse, mutect2, varscan2
- PCDHA1 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 93/133 reads (70%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs368549830; called by muse, mutect2, varscan2
- PEX11G | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs761081474; called by muse, mutect2, varscan2
- RBP3 | c.3602C>T p.S1201L | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as rs1375634622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RP1 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 114/138 reads (83%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.464); catalogued as rs148346976, COSV55112390; called by muse, mutect2, varscan2
- SCN8A | c.5491G>A p.A1831T | Missense Mutation (SNP) | VAF 68/105 reads (65%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.768); catalogued as rs767305170; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCYL3 | c.810C>A p.F270L | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63045051; called by muse, varscan2
- SETD2 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 15/22 reads (68%) | catalogued as COSV57434480, COSV57448778; called by muse, mutect2, varscan2
- SLC32A1 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV99462008; called by muse, mutect2, varscan2
- SPDL1 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs772008391; called by muse, mutect2, varscan2
- STK32B | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 76/104 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs955790754; called by muse, mutect2, varscan2
- TGFBI | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 88/118 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs771481298, COSV59350536; called by muse, mutect2, varscan2
- TP53 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs371409680, CM021154, COSV52693421, COSV52700134, COSV52964971; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- TSSK1B | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs755041373, COSV66814729; called by muse, mutect2, varscan2
- TTN | c.83950G>A p.V27984I (on ENST00000591111; = p.V20560I on NM_003319.4) | Missense Mutation (SNP) | VAF 25/46 reads (54%) | PolyPhen benign (0.129); catalogued as rs764499992; called by muse, mutect2, varscan2
- TTN | c.41246C>T p.P13749L (on ENST00000591111; = p.P6325L on NM_003319.4) | Missense Mutation (SNP) | VAF 43/54 reads (80%) | PolyPhen probably damaging (0.999); catalogued as rs879113967, COSV60194524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZDHHC8 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 52/68 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs149081886; called by muse, mutect2, varscan2
- ZNF787 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54417695; called by muse, mutect2, varscan2
- AEBP1 | c.254-1_264del p.X85_splice | Splice Site (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- ARID1B | c.2138C>A p.P713H | Missense Mutation (SNP) | VAF 60/79 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BTNL9 | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA2D3 | c.2070G>T p.L690F | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD48 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 106/148 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CDS2 | c.352C>A p.H118N | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- CNGB3 | c.1201G>C p.A401P | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GLT6D1 | c.155T>A p.L52H | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- GRID2 | c.823A>G p.R275G | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- HCN1 | c.408C>A p.H136Q | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IMMT | c.498G>C p.E166D | Missense Mutation (SNP) | VAF 56/81 reads (69%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- KIF18B | c.1623G>T p.Q541H (on ENST00000593135 / NM_001265577.2; = p.Q553H on NM_001264573.2) | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- LCLAT1 | c.97del p.S33Lfs*17 | Frame Shift Del (DEL) | VAF 60/99 reads (61%) | called by mutect2, pindel*, varscan2
- LRRC8C | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 84/138 reads (61%) | called by muse, mutect2, varscan2
- MTMR9 | c.1508G>C p.R503T | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR2T10 | c.41T>G p.L14R | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OTX2 | c.694A>T p.N232Y (on ENST00000408990 / NM_172337.3; = p.N240Y on NM_021728.4) | Missense Mutation (SNP) | VAF 191/267 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- PGLYRP4 | c.989T>C p.I330T | Missense Mutation (SNP) | VAF 73/97 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PITX1 | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 64/94 reads (68%) | called by muse, mutect2, varscan2
- PRAMEF7 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.367); called by mutect2, varscan2
- REV1 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SLITRK1 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TEX36 | c.533_540del p.K178Sfs*14 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- TMEM150A | c.760A>T p.S254C (on ENST00000334462 / NM_001031738.3; = p.S201C on NM_153342.3) | Missense Mutation (SNP) | VAF 87/121 reads (72%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- TNNT2 | c.831G>T p.R277S (on ENST00000236918; = p.R274S on NM_000364.4) | Missense Mutation (SNP) | VAF 132/186 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSPYL6 | c.1044C>A p.C348* | Nonsense Mutation (SNP) | VAF 72/106 reads (68%) | called by muse, mutect2, varscan2
- TTN | c.80917_80919del p.G26973del (on ENST00000591111; = p.G19549del on NM_003319.4) | In Frame Del (DEL) | VAF 66/137 reads (48%) | called by pindel, varscan2
- TUBGCP3 | c.503G>T p.C168F | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF689 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 55/89 reads (62%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTR1A | c.868C>T p.L290= | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- ARAP3 | c.1983G>A p.L661= | Silent (SNP) | VAF 112/155 reads (72%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.594C>T p.R198= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs570419348; called by muse, mutect2, varscan2
- CCT8L2 | c.648C>T p.S216= | Silent (SNP) | VAF 51/99 reads (52%) | catalogued as COSV63462044; called by muse, mutect2, varscan2
- CDH4 | c.1434G>A p.A478= | Silent (SNP) | VAF 75/214 reads (35%) | catalogued as rs543161849, COSV64672653; called by muse, mutect2, varscan2
- DBT | c.735G>A p.P245= | Silent (SNP) | VAF 75/101 reads (74%) | catalogued as rs752454574, COSV64496345; called by muse, mutect2, varscan2
- DHX35 | c.915G>A p.G305= | Silent (SNP) | VAF 23/280 reads (8%) | catalogued as COSV52668277; called by muse, mutect2
- DOK1 | c.144G>C p.S48= | Silent (SNP) | VAF 9/179 reads (5%) | called by muse, mutect2
- EBF1 | c.648T>C p.S216= | Silent (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- EXOC4 | c.2274G>A p.Q758= | Silent (SNP) | VAF 63/160 reads (39%) | catalogued as COSV54121570; called by muse, mutect2, varscan2
- F10 | c.729C>T p.D243= | Silent (SNP) | VAF 57/179 reads (32%) | catalogued as rs768291458, COSV65023101; called by muse, mutect2, varscan2
- GPRC5B | c.1158C>T p.N386= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as rs149762584, COSV56027957; called by muse, mutect2, varscan2
- IL3RA | c.399C>T p.D133= | Silent (SNP) | VAF 41/171 reads (24%) | catalogued as rs778940756; called by muse, mutect2, varscan2
- KLK15 | c.288G>A p.P96= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs369450682, COSV56827487; called by muse, mutect2, varscan2
- LRP1B | c.5496G>A p.Q1832= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs1404662535, COSV101258215; called by muse, mutect2, varscan2
- MTUS2 | c.1947G>A p.R649= | Silent (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- MUC16 | c.29541C>T p.S9847= | Silent (SNP) | VAF 129/179 reads (72%) | catalogued as rs762017286, COSV67458133; called by muse, mutect2, varscan2
- NPHP4 | c.3216G>A p.Q1072= | Silent (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- PCDH17 | c.276C>T p.R92= | Silent (SNP) | VAF 52/179 reads (29%) | called by muse, mutect2, varscan2
- PCDHB5 | c.1338C>T p.N446= | Silent (SNP) | VAF 94/126 reads (75%) | catalogued as rs781959722, COSV50647937; called by muse, mutect2, varscan2
- PKN1 | c.1521G>A p.Q507= | Silent (SNP) | VAF 67/82 reads (82%) | catalogued as rs745983344; called by muse, mutect2, varscan2
- RRBP1 | c.219G>A p.K73= | Silent (SNP) | VAF 126/227 reads (56%) | catalogued as COSV104369503; called by muse, mutect2, varscan2
- RYR3 | c.8592G>A p.P2864= (on ENST00000389232; = p.P2865= on NM_001036.6) | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as rs756412825; called by muse, mutect2, varscan2
- SNX19 | c.151C>T p.L51= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as COSV99773753; called by muse, mutect2
- ST8SIA2 | c.381C>T p.F127= | Silent (SNP) | VAF 70/99 reads (71%) | catalogued as rs1322274246, COSV51567200; called by muse, mutect2, varscan2
- STOX2 | c.969C>T p.T323= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as rs544424192; called by muse, mutect2, varscan2
- TMC2 | c.150C>T p.R50= | Silent (SNP) | VAF 22/168 reads (13%) | catalogued as rs1473354870; called by muse, mutect2, varscan2
- TRIM37 | c.2766C>T p.G922= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as rs758418316, COSV51889736; called by muse, mutect2, varscan2
- TRPC4 | c.1161C>A p.I387= | Silent (SNP) | VAF 156/274 reads (57%) | catalogued as COSV100157256; called by muse, mutect2, varscan2
- ALG11 | c.*2735A>G | 3'UTR (SNP) | VAF 9/87 reads (10%) | catalogued as rs1271081329; called by muse, mutect2
- BASP1 | c.*521dup | 3'UTR (INS) | VAF 14/24 reads (58%) | catalogued as rs1169575742; called by mutect2, varscan2
- C16orf82 | c.*860G>A | 3'UTR (SNP) | VAF 88/135 reads (65%) | catalogued as rs547537652; called by muse, mutect2, varscan2
- MUC19 | n.23256C>T | RNA (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2, varscan2
- POP4 | c.7+31G>T | Intron (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- SOCS4 | c.*2045C>A | 3'UTR (SNP) | VAF 8/10 reads (80%) | catalogued as rs528544061; called by muse, varscan2
- SSPOP | n.11792G>A | RNA (SNP) | VAF 30/101 reads (30%) | called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331226 G>A | 5'Flank (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- ZNF518A | chr10:96163619 C>T | 3'Flank (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
